Somatic mutation profile of tumor specimen TCGA-ED-A8O5-01A (aliquot TCGA-ED-A8O5-01A-11D-A35Z-10) from TCGA case TCGA-ED-A8O5, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 59.3 years (21,648 days).
Specimen TCGA-ED-A8O5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94132fcf-edd0-4b0b-a294-9d51bf823da7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A8O5-10A (Blood Derived Normal), aliquot TCGA-ED-A8O5-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/639f54a7-25e0-4ccc-8f15-723fd45224c0

The open-access MAF lists 133 somatic variants for this specimen: 98 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 32, Nonsense Mutation 8, Splice Site 4, Splice Region 2, 5'UTR 2, In Frame Del 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK1 | c.286A>T p.R96W | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99453023; called by muse, mutect2, varscan2
- ANKMY1 | c.1521C>A p.S507R | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV99801257; called by muse, mutect2, varscan2
- ANOS1 | c.208-2A>G p.X70_splice | Splice Site (SNP) | VAF 229/641 reads (36%) | catalogued as COSV99390414; called by muse, mutect2, varscan2
- ATP8B3 | c.3625G>C p.V1209L | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100034005; called by muse, mutect2, varscan2
- AXIN1 | c.1331G>A p.W444* | Nonsense Mutation (SNP) | VAF 27/32 reads (84%) | catalogued as COSV99249265; called by muse, mutect2, varscan2
- AXIN2 | c.1060A>T p.R354* | Nonsense Mutation (SNP) | VAF 42/87 reads (48%) | catalogued as COSV100195896; called by muse, mutect2, varscan2
- BICRA | c.3275A>T p.Q1092L | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV101194228; called by muse, mutect2, varscan2
- BRINP3 | c.68T>A p.L23Q | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100818314; called by muse, mutect2, varscan2
- CCER1 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62646506; called by muse, mutect2, varscan2
- CCT3 | c.899C>A p.A300D | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99827093; called by muse, mutect2, varscan2
- CD70 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99835502; called by muse, mutect2, varscan2
- CDC42BPB | c.4202G>A p.G1401E | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63473763; called by muse, mutect2, varscan2
- CDH18 | c.1913G>T p.R638L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs565236156, COSV56907812, COSV99932062; called by muse, mutect2
- CEP250 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs376769176; called by muse, mutect2, varscan2
- CEP85 | c.1888A>G p.T630A | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV99431737; called by muse, mutect2, varscan2
- CHMP7 | c.105C>G p.F35L | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100500493; called by muse, mutect2, varscan2
- CPA3 | c.474+1G>A p.X158_splice | Splice Site (SNP) | VAF 54/115 reads (47%) | catalogued as COSV56047149, COSV99935950; called by muse, mutect2, varscan2
- CWH43 | c.214C>A p.L72M | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV99892774; called by muse, mutect2, varscan2
- CXorf56 | c.529C>T p.R177C (on ENST00000536133 / NM_001170570.2; = p.R191C on NM_022101.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100233323, COSV57438320; called by muse, mutect2, varscan2
- DDIAS | c.1472G>A p.S491N | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.157); catalogued as COSV100231013; called by muse, mutect2, varscan2
- DMD | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55861718, COSV55871792; called by muse, mutect2, varscan2
- DMP1 | c.397A>T p.R133* | Nonsense Mutation (SNP) | VAF 63/87 reads (72%) | catalogued as COSV99218493; called by muse, mutect2, varscan2
- DMPK | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.997); catalogued as rs540031135, COSV99352729; called by muse, mutect2, varscan2
- DNAH17 | c.5325G>T p.V1775= | Splice Region (SNP) | VAF 18/37 reads (49%) | catalogued as COSV101101420; called by muse, mutect2, varscan2
- DNAH7 | c.2995A>G p.I999V | Missense Mutation (SNP) | VAF 123/298 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758668415, COSV100413804; called by muse, mutect2, varscan2
- DNMT3A | c.1935A>T p.T645= | Splice Region (SNP) | VAF 14/39 reads (36%) | catalogued as rs1166765403, COSV99259067; called by muse, mutect2, varscan2
- DSC1 | c.1354A>G p.T452A | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.253); catalogued as COSV99937163; called by muse, mutect2, varscan2
- DSCAM | c.734C>G p.P245R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101259079; called by muse, mutect2, varscan2
- DZANK1 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.055); catalogued as COSV99361703; called by muse, mutect2, varscan2
- E2F8 | c.687T>A p.H229Q | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100001282; called by muse, mutect2, varscan2
- EGF | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 78/101 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs529423872, COSV99490471; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100348856, COSV57517447; called by muse, mutect2, varscan2
- ENOX2 | c.1498A>G p.K500E (on ENST00000338144 / NM_001382520.1; = p.K471E on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as rs767185454, COSV100583762; called by muse, mutect2, varscan2
- EPHA4 | c.2295T>A p.F765L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV99915547; called by muse, mutect2, varscan2
- EPPK1 | c.4636G>A p.E1546K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as rs191532254; called by muse, mutect2, varscan2
- FAT3 | c.10580G>A p.G3527D | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99961812; called by muse, mutect2, varscan2
- FBN1 | c.8072G>A p.G2691D | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as COSV57317765; called by muse, mutect2, varscan2
- FGF3 | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100490080; called by muse, mutect2, varscan2
- FLG | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 63/192 reads (33%) | catalogued as COSV100910493; called by muse, mutect2, varscan2
- FLG | c.978G>A p.W326* | Nonsense Mutation (SNP) | VAF 63/190 reads (33%) | catalogued as rs1019832328, COSV100910495; called by muse, mutect2, varscan2
- FOXD4 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 102/452 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs770157390, COSV100070580; called by muse, mutect2, varscan2
- FRMD5 | c.94A>G p.T32A | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.228); catalogued as rs762923310, COSV101296258; called by muse, mutect2, varscan2
- GM2A | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100852026; called by muse, mutect2, varscan2
- GRM8 | c.1032C>G p.Y344* | Nonsense Mutation (SNP) | VAF 48/91 reads (53%) | catalogued as COSV100280692; called by muse, mutect2, varscan2
- HSPG2 | c.6302G>A p.R2101H | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs369444110; called by muse, mutect2, varscan2
- IL17RB | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.476); catalogued as COSV55472089, COSV99860996; called by muse, mutect2, varscan2
- IL27RA | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99651911; called by muse, mutect2, varscan2
- INTS12 | c.485G>A p.C162Y | Missense Mutation (SNP) | VAF 52/71 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1352937026, COSV100415669; called by muse, mutect2, varscan2
- KCNA5 | c.1301T>A p.L434Q | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52905005, COSV99363611; called by muse, mutect2, varscan2
- KLHL41 | c.1703T>C p.I568T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99500232; called by muse, mutect2, varscan2
- KRT36 | c.543-1G>A p.X181_splice | Splice Site (SNP) | VAF 23/49 reads (47%) | catalogued as rs1366424181, COSV100057325; called by muse, mutect2, varscan2
- LORICRIN | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 50/197 reads (25%) | PolyPhen benign (0.142); catalogued as COSV100907265; called by muse, mutect2, varscan2
- LRRC43 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs774685084, COSV100336529; called by muse, mutect2, varscan2
- LZTR1 | c.1448A>T p.Q483L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as COSV99301262; called by muse, mutect2, varscan2
- MAB21L1 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs574005569, COSV100076702; called by muse, mutect2, varscan2
- MAP1A | c.7775T>A p.V2592E | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as COSV100288063; called by muse, mutect2, varscan2
- MYOC | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs766083192, COSV50673903, COSV50674762, COSV50680547; called by muse, mutect2, varscan2
- NLRP12 | c.273A>T p.R91S | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV100144830; called by muse, mutect2, varscan2
- NOTCH1 | c.7626C>G p.S2542R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV99485084; called by muse, mutect2, varscan2
- NOTCH2 | c.5533A>C p.S1845R | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV99862739; called by muse, mutect2, varscan2
- NSF | c.1904C>T p.P635L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99833657; called by muse, mutect2, varscan2
- OR11L1 | c.916A>T p.R306* | Nonsense Mutation (SNP) | VAF 52/198 reads (26%) | catalogued as COSV100869381; called by muse, mutect2, varscan2
- OR51E2 | c.502T>G p.C168G | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101211309; called by muse, mutect2, varscan2
- OSBPL9 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100542910, COSV61873662; called by muse, mutect2, varscan2
- PCCA | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as COSV100886524; called by muse, mutect2, varscan2
- PHC1 | c.1342C>A p.P448T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.503); catalogued as COSV101418511; called by mutect2, varscan2
- PPARGC1A | c.2140G>T p.G714* | Nonsense Mutation (SNP) | VAF 38/154 reads (25%) | catalogued as COSV99337227; called by muse, mutect2, varscan2
- PRAMEF20 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 145/198 reads (73%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs779646091, COSV57080721; called by muse, mutect2, varscan2
- PRKAR2B | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99707891; called by muse, mutect2, varscan2
- PRKD1 | c.2507A>T p.H836L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100119288; called by muse, mutect2, varscan2
- PRPF18 | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.605); catalogued as COSV100186963; called by muse, mutect2, varscan2
- PRRC2B | c.5151G>T p.Q1717H | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.564); catalogued as COSV100260842; called by muse, mutect2, varscan2
- PSG6 | c.440A>T p.K147M | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs1406217866, COSV99413544; called by muse, mutect2, varscan2
- RELN | c.6169C>A p.L2057I | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.936); catalogued as COSV100632395; called by muse, mutect2, varscan2
- RFC2 | c.477A>C p.E159D (on ENST00000055077 / NM_181471.3; = p.E125D on NM_002914.4) | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99277698; called by muse, mutect2, varscan2
- RPS6KA3 | c.1640A>G p.Y547C | Missense Mutation (SNP) | VAF 141/331 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101084111; called by muse, mutect2, varscan2
- RPS6KA3 | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as COSV101084113; called by muse, mutect2, varscan2
- SDK2 | c.5177C>T p.A1726V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV101166752; called by muse, mutect2, varscan2
- SEMA3E | c.2308A>T p.R770W | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100317261; called by muse, mutect2, varscan2
- SEMA6A | c.2657C>A p.A886D | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753365134, COSV99145527; called by muse, mutect2, varscan2
- SLC4A8 | c.1972G>A p.V658M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.404); catalogued as rs144293610; called by muse, mutect2, varscan2
- STK38 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs773885454, COSV100007089; called by muse, mutect2, varscan2
- STRA6 | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.306); catalogued as COSV100120793; called by muse, varscan2
- TENM4 | c.4099A>G p.T1367A | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99570943; called by muse, mutect2, varscan2
- TG | c.6238G>T p.V2080F | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV99599004; called by muse, mutect2, varscan2
- TOGARAM2 | c.2675G>A p.R892H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); catalogued as rs371609539; called by muse, mutect2, varscan2
- TREML4 | c.392C>A p.P131Q | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100422811; called by muse, mutect2, varscan2
- TRPM1 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV99855320; called by muse, mutect2, varscan2
- TSPYL2 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 117/297 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100212019; called by muse, mutect2, varscan2
- TTC16 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as COSV100959615; called by muse, mutect2, varscan2
- XYLT1 | c.1970G>T p.R657L | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs748655641, COSV99077145; called by muse, mutect2, varscan2
- ZBTB46 | c.884C>A p.P295Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs770925142, COSV99828755; called by muse, mutect2, varscan2
- ZNF257 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV101448012; called by muse, mutect2, varscan2
- BRD7 | c.1359_1380del p.D454Ifs*7 | Frame Shift Del (DEL) | VAF 28/41 reads (68%) | called by mutect2, pindel, varscan2
- H1-2 | c.8_43del p.E3_P14del | In Frame Del (DEL) | VAF 26/308 reads (8%) | called by mutect2, pindel
- IDUA | c.1342_1350del p.A448_P450del | In Frame Del (DEL) | VAF 66/261 reads (25%) | called by mutect2, varscan2
- IREB2 | c.1195+2dup p.X399_splice | Splice Site (INS) | VAF 29/86 reads (34%) | called by mutect2, pindel, varscan2
- ZNF33A | c.1249_1252del p.C417Gfs*20 (on ENST00000458705 / NM_006974.3; = p.C418Gfs*20 on NM_006954.2) | Frame Shift Del (DEL) | VAF 39/100 reads (39%) | called by mutect2, pindel, varscan2
- ABCC10 | c.4452A>C p.G1484= (on ENST00000372530 / NM_001198934.2; = p.G1456= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/274 reads (20%) | catalogued as COSV99766613; called by muse, mutect2, varscan2
- ADGRE2 | c.1711C>T p.L571= | Silent (SNP) | VAF 57/140 reads (41%) | catalogued as COSV100215681; called by muse, mutect2, varscan2
- APC | c.8061A>T p.S2687= | Silent (SNP) | VAF 62/122 reads (51%) | catalogued as COSV99965159; called by muse, mutect2, varscan2
- BFSP1 | c.664C>A p.R222= | Silent (SNP) | VAF 88/131 reads (67%) | catalogued as COSV100925295; called by muse, mutect2, varscan2
- BMPR2 | c.2025G>A p.K675= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV101001233; called by muse, mutect2, varscan2
- C11orf65 | c.645A>G p.R215= | Silent (SNP) | VAF 60/150 reads (40%) | catalogued as COSV101262717; called by muse, mutect2, varscan2
- C17orf75 | c.414A>C p.T138= | Silent (SNP) | VAF 85/213 reads (40%) | catalogued as COSV99858497; called by muse, mutect2, varscan2
- CACNA1E | c.6246G>A p.E2082= (on ENST00000367573 / NM_001205293.3; = p.E2039= on NM_000721.4) | Silent (SNP) | VAF 46/151 reads (30%) | catalogued as rs778131872, COSV100701280; called by muse, mutect2, varscan2
- CDH9 | c.1176A>T p.V392= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as COSV99141559; called by muse, mutect2, varscan2
- COL6A6 | c.2742C>T p.V914= | Silent (SNP) | VAF 50/96 reads (52%) | catalogued as COSV100649790; called by muse, mutect2, varscan2
- DEGS1 | c.963G>A p.V321= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as COSV100083281; called by muse, mutect2, varscan2
- DENND1B | c.1446A>G p.V482= | Silent (SNP) | VAF 40/145 reads (28%) | called by muse, mutect2, varscan2
- HUWE1 | c.8622T>A p.T2874= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV99470579; called by muse, mutect2
- INSL4 | c.270A>G p.S90= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV99497072; called by muse, mutect2, varscan2
- KCNJ10 | c.1026C>T p.L342= | Silent (SNP) | VAF 32/123 reads (26%) | catalogued as COSV100927864; called by muse, mutect2, varscan2
- LRRC32 | c.30C>T p.A10= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs533407564, COSV52634754, COSV99476661; called by muse, mutect2, varscan2
- MEFV | c.798G>A p.K266= | Silent (SNP) | VAF 44/50 reads (88%) | catalogued as COSV99560254; called by muse, mutect2, varscan2
- MGA | c.4635A>G p.K1545= | Silent (SNP) | VAF 37/67 reads (55%) | catalogued as COSV99578486; called by muse, mutect2, varscan2
- MLN | c.150C>A p.S50= | Silent (SNP) | VAF 37/178 reads (21%) | catalogued as COSV56475696, COSV99803037; called by muse, mutect2, varscan2
- MYO3B | c.2895C>A p.A965= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV100509141; called by muse, mutect2, varscan2
- MYO5C | c.4650C>T p.S1550= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as rs1189744533, COSV55905443; called by muse, mutect2, varscan2
- OR7C1 | c.150C>T p.C50= | Silent (SNP) | VAF 88/186 reads (47%) | catalogued as COSV99934767; called by muse, mutect2, varscan2
- OR7G1 | c.738T>A p.S246= | Silent (SNP) | VAF 49/135 reads (36%) | catalogued as COSV99528405; called by muse, mutect2
- PDE4DIP | c.3009G>A p.Q1003= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV100516379, COSV57703373; called by muse, mutect2, varscan2
- PLAAT2 | c.288A>C p.A96= | Silent (SNP) | VAF 66/120 reads (55%) | catalogued as COSV99738041; called by muse, mutect2, varscan2
- PROM1 | c.31C>T p.L11= | Silent (SNP) | VAF 53/144 reads (37%) | catalogued as COSV71699264; called by muse, mutect2, varscan2
- PRRC2C | c.4677C>T p.N1559= (on ENST00000367742; = p.N1557= on NM_015172.4) | Silent (SNP) | VAF 101/300 reads (34%) | catalogued as COSV100144642; called by muse, mutect2, varscan2
- SCML2 | c.1092T>C p.H364= | Silent (SNP) | VAF 130/302 reads (43%) | catalogued as COSV99318540; called by muse, mutect2, varscan2
- SEMA6D | c.762C>A p.R254= | Silent (SNP) | VAF 50/118 reads (42%) | catalogued as COSV100316418; called by muse, mutect2, varscan2
- SYCP2L | c.1140C>A p.V380= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as COSV99304659; called by muse, mutect2, varscan2
- TAS2R41 | c.42C>T p.S14= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as rs1427173075, COSV101281468; called by muse, mutect2, varscan2
- TTN | c.6723T>A p.A2241= (on ENST00000591111; = p.A2195= on NM_003319.4) | Silent (SNP) | VAF 61/120 reads (51%) | catalogued as COSV100593858; called by muse, mutect2, varscan2
- BIRC8 | n.1642T>G | RNA (SNP) | VAF 44/129 reads (34%) | catalogued as COSV100136321; called by muse, mutect2, varscan2
- CAST | c.-48G>A | 5'UTR (SNP) | VAF 140/311 reads (45%) | catalogued as COSV100352158; called by muse, mutect2, varscan2
- XIRP2 | c.-31C>A | 5'UTR (SNP) | VAF 32/72 reads (44%) | catalogued as COSV99738369; called by muse, mutect2, varscan2
